CCDI case PBBTXH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3ed95b32-38c5-4112-b9b7-78ec2f129e0e

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.0 years (1,107 days).

Biospecimens (3 samples)
- Sample 0DHDZF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHDZS: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHE07: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
